Somatic mutation profile of tumor specimen ALCH-B061-TTP1-A (aliquot ALCH-B061-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B061, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.5 years (23,549 days).
Specimen ALCH-B061-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fedd5b24-0c96-433e-83e0-f6ac2c8fd345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B061-NB1-A (Blood Derived Normal), aliquot ALCH-B061-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2c8b930-f4df-4032-b525-e36dff6db479

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 58/953 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 106/388 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP31 | c.3223G>A p.V1075M | Missense Mutation (SNP) | VAF 27/338 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs777789268, COSV51789384; called by muse, mutect2
- IGKC | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 48/708 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs14246; called by muse, mutect2
- INVS | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs376463532; called by muse, mutect2
- MCM3AP | c.3847G>A p.A1283T | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776810568; called by muse, mutect2
- POT1 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV62928859, COSV62933167; called by muse, mutect2
- PPFIBP2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1439686672; called by muse, mutect2
- SEPTIN14 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.839); catalogued as COSV66429526; called by muse, mutect2
- SMG7 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 40/341 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs748197628; called by muse, mutect2, varscan2
- SZT2 | c.2072T>A p.L691Q | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100987125; called by muse, mutect2
- TLL1 | c.1292T>G p.V431G | Missense Mutation (SNP) | VAF 20/450 reads (4%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV50331308; called by muse, mutect2
- ZAP70 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs1559327875; called by muse, mutect2
- C2orf78 | c.1445T>A p.V482E | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.413); called by muse, mutect2
- CLDN22 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 22/522 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.034); called by muse, mutect2
- KLF5 | c.1254T>G p.D418E | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- MTMR3 | c.2190G>C p.K730N | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); called by muse, mutect2
- PRG4 | c.2838A>C p.E946D | Missense Mutation (SNP) | VAF 75/474 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRPH | c.929A>G p.Q310R | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2
- TNXB | c.9998A>C p.Q3333P (on ENST00000647633; = p.Q3086P on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/651 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.059); called by muse, mutect2
- WSCD2 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AIDA | c.138C>T p.A46= | Silent (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2, varscan2
- GPC6 | c.816C>T p.N272= | Silent (SNP) | VAF 28/389 reads (7%) | catalogued as rs113591716, COSV100988543; called by muse, mutect2
- HES3 | c.201G>C p.S67= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- LMNA | c.666T>C p.H222= | Silent (SNP) | VAF 46/728 reads (6%) | called by muse, mutect2
- TRPV4 | c.210G>A p.K70= | Silent (SNP) | VAF 22/442 reads (5%) | called by muse, mutect2
